Surgical pathology report (de-identified scan), TCGA case TCGA-96-8170, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - NYU, specimen TCGA-96-8170-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. LUNG, SUPERIOR SEGMENT, RIGHT LOWER LOBE
2. 5TH RIB RIGHT
3. STATION 12 LYMPH NODE

DIAGNOSIS:

1. LUNG, RIGHT LOWER LOBE, SUPERIOR SEGMENT: SEGMENTECTOMY
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (1.5 CM).
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- METASTATIC CARCINOMA INVOLVING ONE HILAR LYMPH NODE (1/1).

2. RIB, RIGHT 5TH: EXCISION
- BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOIESIS.

3. LYMPH NODE, LEVEL 12: BIOPSY
- METASTATIC CARCINOMA INVOLVING TWO OF FOUR LYMPH NODES (2/4).
- Specimens: 1: LUNG, SUPERIOR SEGMENT, RIGHT LOWER LOBE
2: 5TH RIB RIGHT
3: STATION 12 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: right lower lobe, superior segment

Procedure: Segmentectomy

Specimen Integrity: Intact

Specimen Laterality: Right

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Squamous cell carcinoma

Histologic Grade: G2: Moderately differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

[page 2 of 4]
1.5cm

Additional Dimension (cm): 1.4cm x 1.2cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by invasive carcinoma

Bronchial Margin Involvement by Squamous Cell Carcinoma in situ (CIS):

Squamous cell carcinoma in situ (CIS) not identified at bronchial margin

Vascular Margin: Uninvolved by invasive carcinoma

Parenchymal Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Present

LYMPH NODES

Extranodal Extension: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus

Regional Lymph Nodes (pN)

pN1: Metastasis in ipsilateral peribronchial and / or ipsilateral hilar lymph nodes, and intrapulmonary nodes including involvement by direct extension

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): respiratory bronchiolitis, focal organizing pneumonia and metaplastic ossification

[REDACTED]

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

[REDACTED] with a RLL squamous cell carcinoma.

MACROSCOPIC DESCRIPTION:

The specimen is received in three parts, each labeled with the patient's name.

1. Part one is received in saline, labeled 'lung, superior segment, right lower lobe'. It consists of a lobe of the lung measuring 9 x

[page 3 of 4]
5.5 x 3.5 cm. Two stapled lines are noted measuring 9 cm and 2.5 cm. The pleura is grey-pink, glistening and mottled lightly with fine black streaks. The bronchial margin measures 2 cm and the vascular margin measures 1 cm. Cut surface of the specimen reveals a light tan firm nodule measuring 1.5 x 1.4 x 1.2 cm, located 1.5 cm from the overlying pleura and 2 cm from the bronchial resection margin. The remainder of the parenchyma is pink-red, crepitant and blotchy. Representative sections are submitted.

2. Part two is received in formalin, labeled '5th rib right'. It consists of a segment of rib measuring 10.5 x 1.0 x 0.5 cm. Scant blood and fibroconnective tissue is attached on the outer surface of bone. The cut surface appears trabeculated and unremarkable. Representative sections are submitted in one cassette following decalcification.

3. Part three is received in saline, labeled 'station 12 lymph node'. It consists of five irregular fragments of tan-brown soft tissue ranging from 0.4 to 1.0 cm in greatest dimension and measuring 1.5 x 1.0 x 0.6 cm in aggregate. Entirely submitted in one cassette.

SUMMARY OF SECTIONS:

1A-1C tumor
1D tumor with overlying pleura
1E random parenchyma
1F stapled line margin
1G vascular margin, shaved
1H bronchial margin, shaved
1I stapled line margin
1J hilar lymph node
2A representative
3A entirely submitted

SPECIAL PROCEDURES:

decalcification.

Attending

Pathologist has evaluated the specimen referred to in the signed

[page 4 of 4]
section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED] Department of Pathology.

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 0e9504d1-820d-4925-ac06-79d4e7ecf185 (TCGA-96-8170.424C9F5D-772D-4F6C-8F73-0090F4FF83CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).